Gene-level copy-number profile of tumor specimen TCGA-D8-A1JC-01A from TCGA case TCGA-D8-A1JC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.0 years (21,898 days).
Specimen TCGA-D8-A1JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.d7bb6fff-6305-4980-ab29-0bb9757b7687.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b366756-bfb4-43ad-b873-423574f1a70f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 16,287; copy number 2: 36,262; copy number 3: 4,759; copy number 4: 1,774; copy number 5: 282; copy number 6: 123; copy number 7: 21; copy number 8: 14; copy number 9: 111; copy number 10: 70; copy number 13: 36; copy number 14: 36; copy number 17: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JC-01A-11D-A13J-01): tumor purity 0.74, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,859,158–87,971,930, 4 genes: KLLN, PTEN, AC063965.2, RPL11P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 731 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,559,992–39,284,917, 61 genes, copy number 6–17 (within-gene range 3–17) (broad region; genes not listed).
- chr10:87,817,928–87,845,612, 1 gene, copy number 5 (within-gene range 0–5): CFL1P1.
- chr11:16,613,132–20,121,601, 98 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr11:56,495,760–57,056,132, 36 genes, copy number 13: AP002512.1, OR5M7P, AP002512.2, OR5M6P, OR5M5P, OR5M11, OR5M10, OR5M13P, OR5M1, OR5AM1P, OR5M12P, OR5AP1P, OR5AP2, OR5AR1, OR2AH1P, TMEM230P2, OR9G1, AP001803.1, OR9G3P, OR9G4, MIR6128, AP001803.10, OR9G2P, OR5G1P, OR5G4P, OR5G5P, OR5G3, LINC02735, FADS2B, OR5AK3P, OR5AK2, OR5AK1P, OR5BQ1P, OR5AK4P, OR5AO1P, OR5BP1P.
- chr11:69,467,598–71,539,209, 48 genes, copy number 9: AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8.
- chr11:72,478,221–78,079,865, 186 genes, copy number 5–14 (broad region; genes not listed).
- chr17:17,200,995–17,677,688, 22 genes, copy number 10: PLD6, AC055811.2, FLCN, AC055811.3, ACTG1P24, COPS3, NT5M, RPL13P12, AC073621.1, TSEN15P1, Y_RNA, MED9, RASD1, AC020558.6, PEMT, AC020558.2, RNU6-468P, AC020558.1, AC020558.5, SMCR2, AC020558.3, AC020558.4.
- chr17:18,605,054–19,336,715, 48 genes, copy number 10 (within-gene range 1–10): Metazoa_SRP, TBC1D28, AC026271.2, AC026271.4, AC026271.1, ZNF286B, FOXO3B, UBE2SP2, TRIM16L, AC026271.3, FBXW10, TVP23B, AC107982.3, AC107982.1, PRPSAP2, RN7SL627P, AC107982.2, AC090286.3, AC090286.2, SLC5A10, AC090286.1, FAM83G, AC090286.4, GRAP, AC003957.1, SNORD3B-1, SNORD3B-2, AC007952.3, KYNUP2, AC007952.7, AC007952.2, AC007952.4, SNORD3D, SNORD3D, GRAPL, AC007952.6, AC007952.9, AC007952.1, AC007952.5, AC007952.8, KYNUP1, SNORD3A, SNORD3C, AC106017.1, KYNUP3, EPN2, AC106017.2, EPN2-AS1.
- chr20:49,632,945–49,988,886, 13 genes, copy number 5: B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1.
- chr20:52,972,358–53,495,330, 1 gene, copy number 7 (within-gene range 4–7): TSHZ2.
- chr20:53,196,229–54,269,542, 20 genes, copy number 7 (within-gene range 5–7): AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.
- chr20:54,859,688–55,075,140, 2 genes, copy number 6: RNU4ATAC7P, RPL12P4.
- chr20:56,369,389–58,619,888, 54 genes, copy number 5 (within-gene range 1–5): AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT.
- chr20:61,252,261–61,940,617, 1 gene, copy number 8 (within-gene range 2–8): CDH4.
- chr20:61,717,506–64,313,132, 140 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,287. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
